Somatic mutation profile of tumor specimen TCGA-DJ-A2PR-01A (aliquot TCGA-DJ-A2PR-01A-11D-A19J-08) from TCGA case TCGA-DJ-A2PR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 27.1 years (9,914 days).
Specimen TCGA-DJ-A2PR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1a89c31-f018-4eef-8e34-4d1e56435efc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PR-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PR-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ee2f854-67e7-4899-a222-c4881ca379df

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CRELD1 | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 6/115 reads (5%) | catalogued as COSV55974965; called by muse, mutect2
- MAP3K3 | c.664A>T p.N222Y | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62281765; called by muse, mutect2, varscan2
- OSBPL9 | c.1859C>G p.S620* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | catalogued as COSV61408776; called by muse, mutect2
- SLC39A7 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63002954; called by muse, mutect2, varscan2
- SUOX | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs541589815, COSV56271552; called by muse, mutect2, varscan2
- THBS1 | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 19/499 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV52955787; called by muse, mutect2
- MYH14 | c.432C>T p.V144= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV51830860; called by muse, mutect2
